Somatic mutation profile of tumor specimen 3799eeb5-c966-4059-a78f-ace269 (aliquot 3799eeb5-c966-4059-a78f-ace269_D6) from CPTAC case 06BR006, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 51.0 years (18,614 days).
Specimen 3799eeb5-c966-4059-a78f-ace269: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 122e25b7-cd8e-4b48-b685-04e80b28d413.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 7e168c2a-f22a-44d9-ac7d-1a4c42 (Blood Derived Normal), aliquot 7e168c2a-f22a-44d9-ac7d-1a4c42_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/077330ce-21bf-471d-b464-e4fdbe129570

The open-access MAF lists 34 somatic variants for this specimen: 19 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 10, Intron 3, Nonsense Mutation 1, 3'Flank 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC107 | c.107-1G>A p.X36_splice | Splice Site (SNP) | VAF 15/110 reads (14%) | catalogued as rs769709863; called by muse, mutect2, varscan2
- CFAP65 | c.2284C>T p.R762* | Nonsense Mutation (SNP) | VAF 20/360 reads (6%) | catalogued as rs756973049, COSV58568377; called by muse, mutect2
- ERBB2 | c.1129C>G p.L377V | Missense Mutation (SNP) | VAF 54/702 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV54072065, COSV54081722; called by muse, mutect2
- FSD1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.46); catalogued as rs141187177; called by muse, mutect2, varscan2
- GPR179 | c.1933G>A p.D645N (on ENST00000621958; = p.D644N on NM_001004334.4) | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.777); catalogued as rs752900382; called by muse, mutect2
- IL1RAP | c.770A>C p.E257A | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV50759750; called by muse, mutect2
- PLP1 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 30/485 reads (6%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.971); catalogued as rs749278720, CM962400, COSV58275616; called by muse, mutect2
- ACACA | c.2122G>C p.D708H | Missense Mutation (SNP) | VAF 62/579 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- ACACA | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 93/707 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ACSL3 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.14); called by muse, mutect2
- ANO5 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- CDK12 | c.4394C>T p.S1465F (on ENST00000447079 / NM_016507.4; = p.S1456F on NM_015083.3) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); called by muse, mutect2
- DLK2 | c.722G>A p.G241D | Missense Mutation (SNP) | VAF 22/453 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- DMAC1 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- ERBB2 | c.2473T>C p.W825R | Missense Mutation (SNP) | VAF 42/716 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM149B1 | c.1640A>G p.Y547C | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ROBO1 | c.4081G>A p.D1361N | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.014); called by muse, mutect2
- RUNX1 | c.437T>C p.F146S (on ENST00000344691 / NM_001001890.3; = p.F173S on NM_001754.5) | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- USP6 | c.2782G>C p.A928P | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AJM1 | c.2650C>T p.L884= | Silent (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- ARHGEF26 | c.2250T>C p.L750= | Silent (SNP) | VAF 15/212 reads (7%) | catalogued as rs748833454; called by muse, mutect2
- IFT46 | c.729C>T p.I243= (on ENST00000264021 / NM_001168618.2; = p.I294= on NM_020153.3) | Silent (SNP) | VAF 16/215 reads (7%) | called by muse, mutect2
- IKZF2 | c.1515C>T p.G505= | Silent (SNP) | VAF 19/244 reads (8%) | called by muse, mutect2
- MTARC2 | c.174G>A p.A58= | Silent (SNP) | VAF 20/194 reads (10%) | catalogued as rs1315147518; called by muse, mutect2
- PCDHGA7 | c.1545C>T p.Y515= | Silent (SNP) | VAF 28/531 reads (5%) | catalogued as rs751427123, COSV53930622; called by muse, mutect2
- SPECC1L | c.2814C>G p.A938= | Silent (SNP) | VAF 58/506 reads (11%) | called by mutect2, varscan2
- TMEM53 | c.588C>T p.H196= | Silent (SNP) | VAF 45/510 reads (9%) | catalogued as rs778915102; called by muse, mutect2
- TMTC1 | c.1020C>T p.V340= (on ENST00000539277 / NM_001193451.2; = p.V232= on NM_175861.3) | Silent (SNP) | VAF 20/195 reads (10%) | catalogued as rs1488845728, COSV55484585; called by muse, mutect2, varscan2
- UBASH3B | c.925C>T p.L309= | Silent (SNP) | VAF 37/430 reads (9%) | called by muse, mutect2
- AC090151.1 | chr8:54701657 G>T | 3'Flank (SNP) | VAF 12/216 reads (6%) | catalogued as rs1407062523; called by muse, mutect2
- AP3B2 | c.360+283C>T | Intron (SNP) | VAF 32/206 reads (16%) | catalogued as rs954026560; called by muse, mutect2, varscan2
- CDKL1 | c.171+17448G>C | Intron (SNP) | VAF 22/367 reads (6%) | called by muse, mutect2
- PCDHGA3 | c.2425-67337G>A | Intron (SNP) | VAF 87/553 reads (16%) | catalogued as rs765970767; called by muse, mutect2, varscan2
- ZNF114 | c.-13G>A | 5'UTR (SNP) | VAF 29/352 reads (8%) | catalogued as rs754358417; called by muse, mutect2
